Somatic mutation profile of tumor specimen MP2PRT-PATFUR-TMP1-A (aliquot MP2PRT-PATFUR-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATFUR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,492 days).
Specimen MP2PRT-PATFUR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d095ac-bef0-4771-bf31-157b848ca6b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFUR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFUR-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e7170e4-c5d7-49d1-82cc-09b645c2688d

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 11, Nonsense Mutation 4, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 128/505 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs397507520, CM021131, CM021132, COSV61007093, COSV61009400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 35/780 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs930105315; called by muse, mutect2
- ADGRA2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as rs200541731; called by muse, varscan2
- FAT4 | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 108/414 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771044290; called by muse, mutect2, varscan2
- IRS4 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 24/618 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.271); catalogued as COSV64533921; called by muse, mutect2
- KIAA0319 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV65497269; called by muse, mutect2, varscan2
- LY75 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs781726712, COSV55109261; called by muse, mutect2, varscan2
- NCOA4 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 13/436 reads (3%) | catalogued as rs1554921132; called by muse, mutect2
- NMNAT3 | c.742G>A p.E248K (on ENST00000296202 / NM_001320512.1; = p.E211K on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/308 reads (27%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1255243987; called by muse, mutect2, varscan2
- NRK | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1450962402, COSV54606610; called by muse, mutect2, varscan2
- PIK3CB | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV56683969; called by muse, mutect2
- PPP1R13L | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 274/701 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as rs1237394114; called by muse, mutect2, varscan2
- PRSS54 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 21/519 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV54686122; called by muse, mutect2
- TRAPPC12 | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 18/640 reads (3%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs1558338955; called by muse, mutect2
- WDR87 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as rs766532444, COSV58203948; called by muse, mutect2, varscan2
- ZRSR2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); catalogued as COSV57065930; called by muse, mutect2
- BCAS1 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 15/512 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTN4 | c.2569G>A p.G857R | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CTCF | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 28/490 reads (6%) | called by muse, mutect2
- IFT172 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 18/397 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IP6K1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 128/451 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LMOD1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 207/528 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRD1 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.219); called by muse, mutect2
- MIPOL1 | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.104); called by muse, mutect2
- N4BP2L1 | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 36/588 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2
- NBPF3 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- OR2J1 | c.896G>C p.R299T | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PTN | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2
- RTCB | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 117/497 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPOCK3 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.397); called by muse, mutect2
- ZMYM2 | c.1943C>G p.S648* | Nonsense Mutation (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- ZNF343 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 13/409 reads (3%) | called by muse, mutect2
- ZNF675 | c.825G>C p.K275N | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- ACSS3 | c.1017T>G p.A339= | Silent (SNP) | VAF 102/386 reads (26%) | called by muse, mutect2, varscan2
- ADAM30 | c.120G>A p.S40= | Silent (SNP) | VAF 19/392 reads (5%) | called by muse, mutect2
- ATG4A | c.627G>A p.Q209= | Silent (SNP) | VAF 228/684 reads (33%) | called by muse, mutect2, varscan2
- BSG | c.63G>T p.G21= | Silent (SNP) | VAF 116/404 reads (29%) | called by muse, mutect2, varscan2
- BSN | c.10398C>T p.Y3466= | Silent (SNP) | VAF 158/438 reads (36%) | catalogued as rs377295244, COSV56520112; called by muse, mutect2, varscan2
- EFCAB8 | c.2196G>A p.L732= | Silent (SNP) | VAF 30/463 reads (6%) | called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 TCACAG>GGT | Silent (DEL) | VAF 72/105 reads (69%) | called by pindel, varscan2*
- SNRNP70 | c.456A>G p.E152= | Silent (SNP) | VAF 17/413 reads (4%) | called by muse, mutect2
- TRAF3IP3 | c.471G>A p.K157= | Silent (SNP) | VAF 125/356 reads (35%) | catalogued as COSV50555471; called by muse, mutect2, varscan2
- TUBGCP5 | c.2403C>T p.L801= | Silent (SNP) | VAF 16/407 reads (4%) | called by muse, mutect2
- ZNF407 | c.5733C>G p.V1911= | Silent (SNP) | VAF 38/505 reads (8%) | called by muse, mutect2
- ARMCX4 | c.1038+1291A>G | Intron (SNP) | VAF 191/511 reads (37%) | called by muse, mutect2, varscan2
- FMN1 | c.2044-2453G>C | Intron (SNP) | VAF 24/457 reads (5%) | called by muse, mutect2
- IGLV4-60 | chr22:22162681 ins TGCC | 3'Flank (INS) | VAF 39/90 reads (43%) | called by mutect2, pindel, varscan2
